Somatic mutation profile of tumor specimen 12ce8313-6c54-4bee-a996-1aa7f8 (aliquot 12ce8313-6c54-4bee-a996-1aa7f8_D6_1) from CPTAC case 11BR074, project CPTAC-2 (Breast — Ductal and Lobular Neoplasms). Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 66.1 years (24,150 days).
Specimen 12ce8313-6c54-4bee-a996-1aa7f8: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 95765821-80b9-4c6a-a354-93fe2e234aaa.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 93f961e1-fe4c-4dfc-8cbe-1dff31 (Blood Derived Normal), aliquot 93f961e1-fe4c-4dfc-8cbe-1dff31_D1_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8af188e5-fc5e-468d-b38e-7d35f40922fb

The open-access MAF lists 27 somatic variants for this specimen: 17 protein-altering or splice-affecting, 8 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Silent 8, Splice Region 1, Intron 1, 3'Flank 1, Nonsense Mutation 1, Splice Site 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTEN | c.635-1G>T p.X212_splice | Splice Site (SNP) | VAF 54/132 reads (41%) | hotspot (GDC flag); catalogued as rs876661024, CS090867, CS993675, COSV64289221, COSV64292432, COSV64296169; ClinVar: likely pathogenic / pathogenic; called by muse, varscan2
- BTBD2 | c.1309G>A p.D437N | Missense Mutation (SNP) | VAF 39/173 reads (23%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.926); catalogued as rs753518835; called by muse, mutect2, varscan2
- COBLL1 | c.1006C>T p.P336S (on ENST00000392717; = p.P298S on NM_014900.5) | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1274577428; called by muse, mutect2, varscan2
- COL4A5 | c.3695G>A p.G1232D | Missense Mutation (SNP) | VAF 29/137 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100090432; called by muse, mutect2, varscan2
- KMT2C | c.3745G>T p.E1249* | Nonsense Mutation (SNP) | VAF 10/33 reads (30%) | catalogued as COSV51318547; called by muse, mutect2, varscan2
- PDZD7 | c.2692dup p.A898Gfs*63 | Frame Shift Ins (INS) | VAF 28/98 reads (29%) | catalogued as rs1177831852; called by mutect2, varscan2
- SAMD11 | c.429C>T p.A143= | Splice Region (SNP) | VAF 67/224 reads (30%) | catalogued as rs148386909; called by muse, mutect2, varscan2
- USHBP1 | c.334G>A p.G112R | Missense Mutation (SNP) | VAF 28/214 reads (13%) | SIFT tolerated (0.58); PolyPhen benign (0.005); catalogued as COSV99394121; called by muse, mutect2, varscan2
- BTF3L4 | c.155C>A p.A52D | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.222); called by muse, mutect2
- CACNG4 | c.664C>A p.L222I | Missense Mutation (SNP) | VAF 24/375 reads (6%) | SIFT tolerated (0.18); PolyPhen benign (0.006); called by muse, mutect2
- DCAF16 | c.539G>T p.G180V | Missense Mutation (SNP) | VAF 67/305 reads (22%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.148); called by muse, mutect2, varscan2
- GATA3 | c.1031A>G p.Y344C | Missense Mutation (SNP) | VAF 132/460 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HERC1 | c.4175C>T p.A1392V | Missense Mutation (SNP) | VAF 11/97 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- MYBPC3 | c.2357A>G p.D786G | Missense Mutation (SNP) | VAF 36/242 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, varscan2
- SASS6 | c.821C>A p.T274N | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.684); called by muse, mutect2, varscan2
- SCUBE1 | c.2911T>C p.S971P | Missense Mutation (SNP) | VAF 7/135 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- WNT3 | c.732G>A p.M244I | Missense Mutation (SNP) | VAF 69/295 reads (23%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- COL14A1 | c.978T>C p.V326= | Silent (SNP) | VAF 37/188 reads (20%) | called by muse, mutect2, varscan2
- MYO3B | c.1407A>G p.L469= | Silent (SNP) | VAF 32/104 reads (31%) | catalogued as rs746413596; called by muse, mutect2, varscan2
- PSG4 | c.966C>T p.D322= | Silent (SNP) | VAF 40/143 reads (28%) | catalogued as rs750504490, COSV54935617; called by muse, mutect2, varscan2
- PSORS1C2 | c.258G>A p.P86= | Silent (SNP) | VAF 13/61 reads (21%) | catalogued as rs1474155439, COSV52535381; called by muse, mutect2, varscan2
- RASA3 | c.441C>T p.L147= | Silent (SNP) | VAF 103/452 reads (23%) | catalogued as rs1029478638, COSV99075754; called by muse, mutect2, varscan2
- SLC2A13 | c.1434A>G p.A478= | Silent (SNP) | VAF 40/234 reads (17%) | catalogued as rs575131050, COSV55110374; called by muse, mutect2, varscan2
- SLIT3 | c.2388T>C p.S796= | Silent (SNP) | VAF 29/170 reads (17%) | called by muse, mutect2, varscan2
- ZC3H3 | c.933C>T p.Y311= | Silent (SNP) | VAF 132/539 reads (24%) | called by mutect2, varscan2
- ASH1L | c.5828+4872G>A | Intron (SNP) | VAF 123/385 reads (32%) | called by muse, mutect2, varscan2
- HARS1 | chr5:140673507 C>G | 3'Flank (SNP) | VAF 104/355 reads (29%) | called by muse, mutect2, varscan2
